Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A3XD, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A3XD-01A (Primary Tumor).

Procurement Date: Laterality:

Path Report: SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, hip

Tumor size: 2 x 0 x 2.5 cm

Tumor features: Ulcerated, Pigmented

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade: Not specified

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Breslow's depth is 5 mm

ICD-O-3

melanoma, NOS

8720/3

Site:

COCF - skin, NOS

C44.9

path - skin, hip

C44.7

5-17-12

RD

Primary Malignancy History		X

Source: NCI Genomic Data Commons file b15d8770-3b4e-411a-84c9-65fa213c716d (TCGA-EB-A3XD.BDCBD4B2-6F4E-4D85-9B28-2B33BF7222F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).